Somatic mutation profile of tumor specimen TCGA-PD-A5DF-01A (aliquot TCGA-PD-A5DF-01A-11D-A27I-10) from TCGA case TCGA-PD-A5DF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 58.6 years (21,414 days).
Specimen TCGA-PD-A5DF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88bce92d-cf94-4bf2-9805-782b5d83b8f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PD-A5DF-10A (Blood Derived Normal), aliquot TCGA-PD-A5DF-10A-01D-A27I-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/246ea489-0b42-4a59-85fe-93db19e7700d

The open-access MAF lists 50 somatic variants for this specimen: 35 protein-altering or splice-affecting, 7 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 7, Frame Shift Del 4, RNA 3, Intron 2, In Frame Del 2, 3'UTR 2, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1721_1723del p.R574del (on ENST00000521381 / NM_181523.3; = p.R304del on NM_181504.4) | In Frame Del (DEL) | VAF 56/101 reads (55%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- AAMP | c.110C>G p.P37R | Missense Mutation (SNP) | VAF 158/429 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.612); catalogued as COSV50307176, COSV50307203; called by muse, mutect2, varscan2
- BARD1 | c.1589C>T p.P530L | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53610278; called by muse, mutect2, varscan2
- CCNB3 | c.3853A>G p.I1285V | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV52071454, COSV52071763; called by muse, mutect2, varscan2
- CHST9 | c.548A>T p.Q183L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as COSV52433263; called by muse, mutect2, varscan2
- COL14A1 | c.5174G>A p.R1725Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.45); catalogued as rs1484515277, COSV52850469; called by muse, mutect2, varscan2
- CORO2B | c.1042G>T p.G348C | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55951550, COSV99963413; called by muse, mutect2, varscan2
- DCC | c.4057C>G p.P1353A | Missense Mutation (SNP) | VAF 84/265 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.088); catalogued as COSV71429214; called by muse, mutect2, varscan2
- EN2 | c.167C>A p.A56E | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as COSV52082938; called by muse, mutect2, varscan2
- FGD5 | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.011); catalogued as COSV53239719; called by muse, mutect2, varscan2
- FSIP2 | c.19495G>A p.V6499M | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58082049; called by muse, mutect2, varscan2
- HNRNPM | c.254A>G p.Q85R | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57692049; called by muse, mutect2, varscan2
- IL10RA | c.222C>A p.N74K | Missense Mutation (SNP) | VAF 96/289 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.086); catalogued as COSV57140071; called by muse, mutect2, varscan2
- KLHL32 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 85/165 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs752627797, COSV65111334; called by muse, mutect2, varscan2
- MLLT10 | c.485G>T p.C162F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56993409; called by muse, mutect2, varscan2
- NLE1 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 86/265 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV62603913, COSV62604923; called by muse, mutect2, varscan2
- NME5 | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.705); catalogued as COSV54522353; called by muse, mutect2, varscan2
- OR51B6 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 80/212 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); catalogued as rs1374953820, COSV66512619; called by muse, mutect2, varscan2
- OVCH1 | c.1604C>T p.S535F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV58961167; called by muse, mutect2, varscan2
- POTEH | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 124/506 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV58881478; called by muse, mutect2, varscan2
- PPP1R1B | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV54201747; called by muse, mutect2, varscan2
- RFX6 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs931311046, COSV60584152; called by muse, mutect2, varscan2
- RMDN1 | c.83C>A p.S28* | Nonsense Mutation (SNP) | VAF 5/9 reads (56%) | catalogued as rs781028658, COSV52205218; called by muse, mutect2, varscan2
- STRIP2 | c.2241G>C p.W747C | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50803633; called by muse, varscan2
- TPO | c.2591G>T p.G864V | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV61098114; called by muse, mutect2, varscan2
- VPS13D | c.10243T>C p.F3415L | Missense Mutation (SNP) | VAF 96/190 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV50629224; called by muse, mutect2, varscan2
- YPEL1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 42/396 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs1204032355, COSV59756422; called by muse, mutect2
- ZBTB2 | c.168G>C p.Q56H | Missense Mutation (SNP) | VAF 78/233 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1415634952, COSV57312098; called by muse, mutect2, varscan2
- ZNF280C | c.1759T>A p.S587T | Missense Mutation (SNP) | VAF 86/211 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.039); catalogued as COSV63968701; called by muse, mutect2, varscan2
- CSAG3 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 216/1071 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- EED | c.673_681del p.L225_A227del | In Frame Del (DEL) | VAF 29/113 reads (26%) | called by pindel, varscan2
- MTERF1 | c.1055_1061del p.L352Qfs*3 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | called by mutect2, pindel, varscan2
- PRICKLE2 | c.376_385del p.K126Sfs*29 (on ENST00000295902; = p.K70Sfs*29 on NM_198859.4) | Frame Shift Del (DEL) | VAF 50/166 reads (30%) | called by mutect2, pindel, varscan2
- QRICH2 | c.356_368del p.A119Vfs*97 | Frame Shift Del (DEL) | VAF 33/112 reads (29%) | called by mutect2, pindel, varscan2
- ZSCAN1 | c.1072del p.R358Gfs*92 | Frame Shift Del (DEL) | VAF 47/145 reads (32%) | called by mutect2, pindel, varscan2
- AP4E1 | c.798C>T p.H266= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as COSV55916016; called by muse, mutect2, varscan2
- CACNA2D3 | c.1699C>A p.R567= | Silent (SNP) | VAF 63/180 reads (35%) | catalogued as COSV55525675; called by muse, mutect2, varscan2
- KAT2B | c.360C>G p.P120= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV55427828; called by muse, mutect2, varscan2
- MYH1 | c.2841G>A p.L947= | Silent (SNP) | VAF 71/166 reads (43%) | called by muse, mutect2, varscan2
- SLC47A1 | c.489A>T p.P163= | Silent (SNP) | VAF 62/96 reads (65%) | catalogued as COSV54499740; called by muse, mutect2, varscan2
- SORCS2 | c.1953G>A p.E651= | Silent (SNP) | VAF 63/152 reads (41%) | catalogued as rs867776408, COSV61166229; called by muse, mutect2, varscan2
- SYNE3 | c.1848C>T p.P616= | Silent (SNP) | VAF 54/159 reads (34%) | catalogued as COSV62078789; called by muse, mutect2, varscan2
- ABHD18 | c.699+1055_699+1074del | Intron (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel
- AP002414.1 | n.40C>G | RNA (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- CASR | c.1378-6208A>G | Intron (SNP) | VAF 88/223 reads (39%) | catalogued as rs753238660, COSV56135777; called by muse, mutect2, varscan2
- CENPE | c.-17C>T | 5'UTR (SNP) | VAF 35/74 reads (47%) | catalogued as rs1447072513, COSV99478083; called by muse, mutect2, varscan2
- GJA1 | c.*370T>G | 3'UTR (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99247020; called by mutect2, varscan2
- LINC00840 | n.142C>T | RNA (SNP) | VAF 70/192 reads (36%) | called by muse, mutect2, varscan2
- SSPOP | n.14977C>G | RNA (SNP) | VAF 10/35 reads (29%) | catalogued as rs773536375, COSV65128427; called by muse, mutect2, varscan2
- ZSCAN21 | c.*285G>A | 3'UTR (SNP) | VAF 64/205 reads (31%) | catalogued as COSV52849883; called by muse, mutect2, varscan2
